Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IJ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IJ-01A (Primary Tumor).

[page 1 of 5]
Pathology Report – Corrected Report

Corrected Report Comment

This report is being issued to correct the clinical history for this patient. It should be: a history of pancreatic neuroendocrine tumor, surgery.

Final Diagnosis

- A. LYMPH NODE, PERIDUODENAL, BIOPSY:
One lymph node, negative for malignancy (0/1).
- B. GALLBLADDER, CHOLECYSTECTOMY:
No significant abnormality recognized.
- C. LYMPH NODE, RETROPERITONEAL, BIOPSY:
One lymph node with sinus histiocytosis, negative for malignancy.
- D. PANCREAS, PANCREATODUODENECTOMY:
Pancreatic endocrine neoplasm.
See Key Pathological Findings.
Tumor size 3.5 cm.
Gross configuration: solitary and well circumscribed.
Mitotic counts is 0/10 per high power fields.
Neoplasm is confined to the pancreas.
No lymphatic, vascular perineural invasion.
All margins are free of neoplasia.
Focal PanIN-3 in an area of atrophic pancreas.
Retention cyst noted in the adjacent pancreas.
Sixteen lymph nodes are free of metastatic disease.
- E. OMENTUM, EXCISION:
Adipose tissue with no diagnostic abnormality recognized.
- F. FINAL PANCREATIC MARGIN, RESECTION:
Pancreatic parenchyma with necrosis, and retention cyst.
Negative for neoplasm.
- G. OMENTUM, EXCISION:
Benign omental adipose tissue.

*ICD-O-3
Neuroendocrine carcinoma, NOS
8246/3
Site: Pancreas head
C25.0
J2 4/16/14*

I, _____, the attending pathologist, personally reviewed all slides and/or materials and rendered the final diagnosis Electronically Signed Out by _____

Key Pathological Findings

D: Pancreas-Endocrine Synoptic Data

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

*TUMOR SITE:

*Pancreatic head

[page 2 of 5]
TUMOR FOCALITY: Unifocal

*TUMOR CONFIGURATION:

*Circumscribed

*Solid, partially encapsulated

TUMOR SIZE: 3.5 cm

*OTHER ORGANS SUBMITTED: *None

HISTOLOGIC TYPE: Pancreatic endocrine tumor:

Well differentiated

*FUNCTIONAL TYPE: *Pancreatic endocrine tumor, secretory status unknown

EXTENT OF INVASION - PRIMARY TUMOR: Tumor limited to pancreas

REGIONAL LYMPH NODES: No regional lymph node metastasis

Number examined: 16

Number involved: 0

DISTANT METASTASIS: Cannot be assessed

MARGINS:

Margins free of tumor

*VENOUS LARGE VESSEL INVASION (V):

*VENOUS LARGE VESSEL INVASION (V): *Absent

*LYMPHATIC (SMALL VESSEL) INVASION (L): *Absent

*PERINEURAL INVASION: *Absent

*MITOTIC ACTIVITY: *Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

PanIN 3

ANCILLARY STUDIES:

1

Insulin

Negative

Glucagon

Negative

Pancreatic Polypeptide

Negative

Vasoactive Intestinal Polypeptide

Negative

Gastrin

Negative

Specimen(s) Received

- A PERI-DUODENAL NODE
- B GALLBLADDER
- C RETROPERITONEAL NODES
- D WHIPPLE 4 FS
- E OMENTUM
- F FINAL PANCREATIC MARGIN
- G OMENTUM (ADDITIONAL)

Clinical History

History of pancreatic neuroendocrine tumor, status post

urgery.

Preoperative Diagnosis

[page 3 of 5]
Pancreatic neuroendocrine tumor.

Frozen Section Diagnosis

FSD1. WHIPPLE (RETROPERITONEAL):
Negative.

FSD2-D3: WHIPPLE, PANCREATIC MARGIN:
Negative.

FSD4. WHIPPLE, COMMON BILE DUCT MARGIN:
Negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr. _____ in _____.

I, _____, M.D., have performed the intraoperative consultation (s) and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "periduodenal nodule". The specimen consists of a single, ovoid, rubbery lymph node measuring up to 1.3 cm in greatest dimension. There is a moderate amount of adipose tissue attached to the lymph node. No tissue was submitted to the Tissue Procurement Laboratory. The lymph node is bisected and is submitted entirely in 1 cassette A.

B. The specimen is labeled "gallbladder". The specimen consists of a gallbladder which measures 9.5 x 3.5 x 3.5 cm. The serosa of the gallbladder is pink tan to dusky purple, smooth and glistening. No transmural perforations are grossly identified. The gallbladder content consists of a large amount of dark-green viscous bile. No gallstones are grossly identified. The mucosa of the gallbladder is velvety, dark green. The gallbladder wall is averaging 0.2 cm in thickness. No lymph nodes are grossly identified attached to the gallbladder neck. No tissue was submitted to the Tissue Procurement Laboratory. The cystic duct is patent to the flow of bile and has a 0.2 cm in diameter lumen. Representative sections of the specimen are submitted in 2 cassettes, B1 and B2.

C. The specimen is labeled "retroperitoneal node". The specimen consists of an irregular, unoriented fragment of fibroadipose tissue measuring 3 x 2 x 1 cm. The specimen is serially sectioned to reveal a single potential lymph node which measures up to 1.0 cm in greatest dimension. No tissue was submitted to the Tissue Procurement Laboratory. The specimen is submitted entirely in 4 cassettes, C1-C4, with potential lymph node in cassette C2.

D. The specimen is labeled "Whipple, stitch is retroperitoneal margin". The specimen consists of a head of pancreas (7 x 5 x 3.5 cm), with adjacent portion of duodenum (25 cm in length and up to 3.5 cm in circumference at the distal resection margins) and distal portion of stomach (7.5 cm in length and up to 12.0 cm in circumference at the proximal gastric margin). The serosa of the stomach is pink tan, mildly congested, smooth, glistening, while the outer surface of the duodenum is shaggy with a small amount of fibroadipose tissue attached. There is moderate amount of lesser and greater omental adipose tissue attached to the gastric wall. The pancreatic resection margin reveals a pink tan, lobulated and grossly unremarkable pancreatic parenchyma. The peripheral aspects of the

[page 4 of 5]
pancreatic head are composed of a small amount of yellow tan lobulated adipose tissue which is ranging from 0.1 to 0.5 cm in thickness. Prior to sectioning the specimen is inked as follows:

Green:	Anterior aspect of the pancreatic head
Black:	Superior aspect of the pancreatic resection margin
Orange:	Inferior aspect/uncinate process
Red:	Medial aspect
Blue:	Retroperitoneal aspect.

On opening the stomach reveals a pink tan, smooth, glistening mucosa which shows preservation of rugae. Six distal cm of the duodenal mucosa has dusky red color. The remaining mucosa of the duodenum is pink tan, smooth, glistening, and has the usual intestinal folds. The ampulla of Vater is slightly prominent and grossly unremarkable. The common bile duct and main pancreatic duct are grossly unremarkable. On sectioning the pancreatic head reveals a roughly ovoid, well defined, rubbery tumor mass which measures up to 3.5 x 2.5 x 2 cm. The tumor partially involves uncinate process and is 0.1 cm from the closest inferior and medial aspects of pancreatic head. The tumor is 2.8 cm from the pancreatic resection margin, 1.2 cm from the retroperitoneal margin, and 0.5 cm from anterior aspect of the pancreatic head. The cut surface of the tumor is pink tan, homogenous, without evidence of necrosis or hemorrhage. The remainder of the pancreatic parenchyma is pink tan, lobulated, and grossly unremarkable. On sectioning the adipose tissue of the peripheral aspects of the pancreatic head, several potential lymph nodes are grossly identified which measure up to 0.2 cm in greatest dimension. Representative sections of the specimen are submitted for frozen section analysis and frozen section remnants are submitted in 4 cassettes as follows:

FSD1:	Retroperitoneal resection margin closest to tumor
FSD2-D3:	Pancreatic resection margin, tangential section
FSD4:	Common bile duct margin, tangential section.

Representative sections of the specimen are submitted to the Tissue Procurement Laboratory.

Additional sections of the specimen are submitted in 46 cassettes as follows:

D5:	Mirror image of the section submitted to the Tissue Procurement Laboratory
D6-D8:	Gastric resection margin, tangential section
D9:	Duodenal resection margin, tangential section
D10:	Ampulla of Vater with distal portion of common bile duct
D11:	Ampulla of Vater with distal portion of main pancreatic duct
D12:	Tumor in relation to the wall of main pancreatic duct
D13:	Tumor in relation to the wall of common bile duct
D14:	Tumor in relation to the duodenal wall
D15:	Tumor involving uncinate process in relation to the closest inferior aspect of the pancreatic head
D16-D17:	Tumor in relation to the anterior aspect of the pancreatic head
D18:	Tumor in relation to the closest medial aspect of the pancreatic head
D19:	Additional section of the tumor in relation to the retroperitoneal aspect
D20-D22:	The remainder of the fibroadipose tissue of anterior aspect of pancreatic head
with potential lymph nodes	
D23-D24:	The remaining fibroadipose tissue of the medial aspect of the pancreatic head
D25-D28:	The remaining fibroadipose tissue of the superior aspect of the pancreatic head
D29-D31:	The remaining fibroadipose tissue of the inferior aspect of the pancreatic head
D32-D38:	The remaining fibroadipose tissue of the retroperitoneal aspect
D39-D41:	Lesser omentum adipose tissue with potential lymph nodes
D42-D44:	Greater omentum adipose tissue with potential lymph nodes
D45-D50:	Additional sections of the tumor.

[page 5 of 5]
E. The specimen is labeled "omentum". The specimen consists of an irregular, unoriented portion of greater omentum which measures 13 x 15 and ranges from 0.1 to 2.5 cm in thickness. On sectioning the specimen reveals multiple subserosal foci of hemorrhage which range from 0.1 to 1.0 cm in greatest dimension. No other lesions are grossly identified. No tissue was submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 2 cassettes, E1 and E2.

F. The specimen is labeled "final pancreatic margin". The specimen consists of an irregular, unoriented fragment of pancreatic parenchyma which measures 2.5 x 1.5 x 0.4 cm. No tissue was submitted to the Tissue Procurement Laboratory. The specimen is submitted entirely in 1 cassette F.

G. The specimen is labeled "omentum". The specimen consists of an irregular, unoriented portion of omentum which measures up to 23 x 10, and is ranging from 0.5 to 1.7 cm in thickness. The specimen is serially sectioned to reveal multiple irregular areas of hemorrhage which range from 0.1 to 1.0 cm in greatest dimension. No tumor or other lesions are grossly identified. No tissue was submitted to the Tissue Procurement Laboratory. Representative sections of the omentum with the areas of hemorrhage are submitted in 2 cassettes, G1 and G2.

Source: NCI Genomic Data Commons file 7c8bb52f-5a38-4c48-8211-82c45331abb4 (TCGA-3A-A9IJ.5DFA5593-F509-463C-A384-0A7F07B1B2BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).